Somatic mutation profile of tumor specimen TCGA-J8-A4HY-01A (aliquot TCGA-J8-A4HY-01A-11D-A257-08) from TCGA case TCGA-J8-A4HY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 68.7 years (25,106 days).
Specimen TCGA-J8-A4HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8f81893-c8c6-4d28-b480-b586262175d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A4HY-10A (Blood Derived Normal), aliquot TCGA-J8-A4HY-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eabea56b-cf64-4a62-a401-fabd635e7e90

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 3, Intron 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKLE1 | c.1546C>T p.Q516* (on ENST00000394458; = p.Q462* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | catalogued as COSV101082150; called by muse, mutect2, varscan2
- AP5B1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs917788015, COSV100375938; called by muse, mutect2, varscan2
- C16orf82 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs760707854; called by muse, mutect2, varscan2
- COG4 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.985); catalogued as rs1216838296, COSV100091457; called by muse, mutect2, varscan2
- CRHR1 | c.569C>T p.A190V (on ENST00000398285 / NM_001145146.2; = p.A161V on NM_004382.5) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99523403; called by muse, mutect2, varscan2
- DGKB | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99337501; called by muse, mutect2, varscan2
- DISP3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99607430, COSV99607787; called by muse, mutect2
- GPC5 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100993146; called by muse, mutect2
- GPR42 | c.769T>G p.W257G | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101497375; called by muse, mutect2, varscan2
- HCN1 | c.2398C>G p.L800V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.058); catalogued as COSV100299243, COSV100300086, COSV57536982; called by muse, mutect2, varscan2
- HIRIP3 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs775591825, COSV99662916; called by muse, mutect2, varscan2
- HPN | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV99384941; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs766023558; called by muse, mutect2
- MOCS3 | c.1286C>G p.S429* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV99724203; called by muse, mutect2, varscan2
- MUC2 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1228909780; called by muse, mutect2
- PALM2AKAP2 | c.1399A>G p.T467A (on ENST00000259318 / NM_001136562.3; = p.T698A on NM_007203.5) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV99394884; called by muse, mutect2, varscan2
- PC | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58993349; called by muse, mutect2, varscan2
- PHAX | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV99881338; called by muse, mutect2, varscan2
- POR | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100115518; called by muse, mutect2
- PPAN-P2RY11 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs868864799, COSV53453245; called by muse, mutect2
- PTPN13 | c.6584C>A p.A2195D (on ENST00000411767 / NM_080683.3; = p.A2176D on NM_006264.3) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100364311; called by muse, mutect2
- RTF1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101047540, COSV67477990; called by muse, mutect2, varscan2
- SH3BP4 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60643298; called by muse, mutect2, varscan2
- SH3TC1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs758701705, COSV99794573; called by muse, mutect2, varscan2
- SLC4A8 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100176551; called by muse, mutect2, varscan2
- SORL1 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99492851; called by muse, mutect2, varscan2
- TAFA5 | c.196G>A p.A66T (on ENST00000402357 / NM_001082967.3; = p.A59T on NM_015381.7) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747062623, COSV100385561; called by mutect2, varscan2
- TRIM23 | c.1618A>T p.S540C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99139894; called by muse, mutect2, varscan2
- UTP20 | c.6644T>G p.I2215S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99881059; called by muse, mutect2, varscan2
- TECPR2 | c.3753_3755del p.M1251_L1252delinsI | In Frame Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel
- TIGD6 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- ABL1 | c.2361G>A p.V787= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100583619; called by muse, mutect2, varscan2
- BIN1 | c.735C>T p.I245= (on ENST00000316724 / NM_001320642.1; = p.I214= on NM_004305.4) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs184358580, COSV99387700; called by muse, mutect2
- CFAP251 | c.264G>A p.E88= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99945582; called by muse, mutect2, varscan2
- FKBP9 | c.312C>T p.N104= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs572685017, COSV99639165; called by muse, mutect2, varscan2
- IFT80 | c.2154C>T p.Y718= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100425030; called by muse, mutect2
- NGF | c.630G>A p.A210= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs112292538, COSV101049327; called by muse, mutect2, varscan2
- PTTG1IP | c.345C>T p.I115= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100445834; called by muse, varscan2
- MFRP | chr11:119343922 C>A | 5'Flank (SNP) | VAF 27/105 reads (26%) | catalogued as COSV64128902; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16666A>G | Intron (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
